Surgical pathology report (de-identified scan), TCGA case TCGA-26-1442, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-1442-01A (Primary Tumor).

[page 1 of 2]
Case Type: [REDACTED]
Accession #: [REDACTED]
Name: [REDACTED]
MRN: [REDACTED]
Pt. Location: [REDACTED]
Date Received: [REDACTED]
Date of Collection: [REDACTED]
Ref. MD: [REDACTED]

26-1442

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Brain tumor (88307)	A. Frozen Section Charge (88331)	
B. Brain tumor (88307)	B. Frozen Section Charge (88331)	B.
KI-67, Nuclear Antigen, Mib1 (88342)	B. Glial Fibrill. Acid Prt (88342)	
C. Brain tumor (88307)	C. KI-67, Nuclear Antigen, Mib1 (88342)	
C. Glial Fibrill. Acid Prt (88342)		

CLINICAL HISTORY: [REDACTED] hospital-to-hospital transfer for left frontal brain tumor. Patient with disorientation, slurred speech, headache, unsteady gait.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Brain tumor
- B. Brain tumor
- C. Brain tumor

A. The specimen is received fresh designated "brain tumor" and consists of a 0.9 x 0.8 x 0.6 cm aggregate of tan to beige edematous soft tissue pieces. A representative portion is submitted for frozen section. Frozen section diagnosis is "Diffuse infiltrating glioma, suspect malignant glioma" by [REDACTED]. The frozen tissue is submitted in cassette FSA1, and the remaining tissue is submitted in cassette A2. [REDACTED]

B. The specimen is received fresh designated "brain tumor" and consists of a 2.4 x 2.4 x 0.8 cm portion of beige to pink soft tissue pieces. A representative portion is submitted for frozen section. Frozen section diagnosis is "Diffuse infiltrating glioma, suspect malignant glioma" by [REDACTED]. The frozen tissue is submitted in cassette FSB1, and a portion of the remaining tissue is submitted for [REDACTED] the remaining tissue is submitted in cassettes B2 and B3. [REDACTED]

C. The specimen is received fresh designated "brain tumor" and consists of a 3.9 x 3.3 x 0.8 cm aggregate of beige to gray-tan soft tissue pieces. A representative portion is submitted for the [REDACTED] and the remaining tissue is submitted in cassettes C1 and C2. [REDACTED]

DIAGNOSIS:

[REDACTED]

[page 2 of 2]
- [REDACTED]
- A. "Brain tumor":
Glioblastoma multiforme (WHO Grade IV astrocytoma)
- B. "Brain tumor":
Glioblastoma multiforme (WHO Grade IV astrocytoma)
- C. "Brain tumor":
Glioblastoma multiforme (WHO Grade IV astrocytoma)

(see comment)

COMMENT: Many sections show a highly infiltrative, non-uniform glial neoplasm that in some areas shows low to intermediate-grade histology. However, section "B3" reveals areas of increased cellularity, pleomorphism, vascular proliferation and necrosis. Many tumor cells are strongly reactive for GFAP and the ki-67 labeling index varies from low to high in low and high grade areas of the tumor, respectively. These results support the diagnosis.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

ICD9 Codes: 191.9

[REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist

Electronically signed [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 8fdaf3b6-b436-4add-aeb2-1038f811ef85 (TCGA-26-1442.D371CEF9-7C69-4A72-93A2-33B9741C44CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).